Somatic mutation profile of tumor specimen TCGA-86-8673-01A (aliquot TCGA-86-8673-01A-11D-2393-08) from TCGA case TCGA-86-8673, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.8 years (22,571 days).
Specimen TCGA-86-8673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8f2869c-be4d-4112-8508-9de3d1141105.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8673-10A (Blood Derived Normal), aliquot TCGA-86-8673-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c4ea4ee-dcfc-4481-80ed-c146c2ff9818

The open-access MAF lists 512 somatic variants for this specimen: 390 protein-altering or splice-affecting, 111 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 111, Nonsense Mutation 38, Frame Shift Del 19, Splice Site 8, Intron 5, Splice Region 4, RNA 3, 3'UTR 2, In Frame Del 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.5874G>T p.W1958C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99419395; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51022223, COSV99257209; called by muse, mutect2
- A2ML1 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432449630, COSV100229258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AADAC | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99233434; called by muse, mutect2, varscan2
- ABT1 | c.22A>T p.K8* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99223312; called by muse, mutect2
- AC136428.1 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 102/304 reads (34%) | catalogued as COSV101434982, COSV101434991; called by muse, mutect2, varscan2
- ACOX1 | c.1742C>G p.T581R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99503843; called by muse, mutect2, varscan2
- ACP1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV99681763; called by muse, mutect2, varscan2
- ACP7 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV100488571, COSV58699463; called by muse, mutect2, varscan2
- ACTL6A | c.848C>G p.P283R | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101199713; called by muse, mutect2, varscan2
- ADAM12 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1330050371, COSV100901100; called by muse, mutect2, varscan2
- ADAM7 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV104385189, COSV99444647; called by muse, mutect2, varscan2
- ADAMTS16 | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99942265; called by muse, mutect2, varscan2
- ADCY5 | c.3043G>T p.D1015Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100568098, COSV59193958, COSV59200585; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100416765; called by muse, mutect2, varscan2
- AGAP6 | c.1045G>T p.G349C (on ENST00000374056 / NM_001365867.1; = p.G372C on NM_001077665.2) | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100929073; called by muse, mutect2, varscan2
- AHDC1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs765084436, COSV99899623; called by muse, mutect2, varscan2
- AKAP17A | c.430del p.E144Sfs*18 | Frame Shift Del (DEL) | VAF 51/308 reads (17%) | catalogued as COSV58308392; called by mutect2, pindel, varscan2
- AL592490.1 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV101308257; called by muse, mutect2
- ALAS2 | c.1481T>A p.L494H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238528, COSV58191922; called by muse, mutect2, varscan2
- ANK3 | c.4456A>T p.R1486* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55061422, COSV99781522; called by muse, mutect2, varscan2
- APLP1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV55704099; called by muse, mutect2, varscan2
- APOB | c.4220C>T p.S1407F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV99267088; called by muse, mutect2, varscan2
- ARHGAP25 | c.1594C>A p.L532I (on ENST00000409202 / NM_001007231.3; = p.L524I on NM_014882.3) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99771884; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1237A>G p.M413V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100771978; called by muse, mutect2, varscan2
- ASCC3 | c.6151G>C p.E2051Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1396205297, COSV100976798; called by muse, mutect2, varscan2
- ASMTL | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as rs1330596203, COSV101187879; called by muse, mutect2, varscan2
- ASPM | c.7215G>T p.K2405N | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99660881; called by muse, mutect2, varscan2
- ASXL3 | c.2153C>A p.P718Q | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99325968; called by muse, mutect2, varscan2
- ASXL3 | c.5059C>A p.P1687T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99325969; called by muse, mutect2, varscan2
- ATP10B | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100469635; called by muse, mutect2, varscan2
- ATP11A | c.2741C>A p.T914N | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99369498; called by muse, mutect2, varscan2
- ATP6V1E1 | c.367-1G>T p.X123_splice | Splice Site (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99494406; called by muse, mutect2, varscan2
- ATRNL1 | c.2501T>A p.L834Q | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100372244; called by muse, mutect2, varscan2
- BCAT2 | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100302519; called by muse, mutect2, varscan2
- BTNL3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV100732231; called by muse, mutect2
- C10orf90 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99504774; called by muse, mutect2
- C17orf64 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768426490, COSV99293573; called by muse, mutect2, varscan2
- C1orf94 | c.1192T>A p.F398I (on ENST00000488417 / NM_001134734.2; = p.F208I on NM_032884.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.336); catalogued as COSV100975152; called by muse, mutect2
- C3orf33 | c.677T>C p.L226S (on ENST00000340171 / NM_001308229.2; = p.L183S on NM_173657.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.663); catalogued as COSV100420143; called by muse, mutect2, varscan2
- C9orf43 | c.792C>G p.H264Q | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV99928532; called by muse, mutect2, varscan2
- CADM2 | c.765G>T p.L255= (on ENST00000407528 / NM_001167674.2; = p.L257= on NM_153184.4) | Splice Region (SNP) | VAF 26/146 reads (18%) | catalogued as COSV101058330, COSV67363279; called by muse, mutect2, varscan2
- CADPS | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV99340073; called by muse, mutect2, varscan2
- CALB2 | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100226367; called by muse, mutect2, varscan2
- CAMSAP2 | c.2515G>T p.G839* (on ENST00000236925 / NM_001297707.2; = p.G828* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 114/230 reads (50%) | catalogued as COSV99373920; called by muse, mutect2, varscan2
- CAMSAP2 | c.2516G>T p.G839V (on ENST00000236925 / NM_001297707.2; = p.G828V on NM_203459.3) | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99373925; called by muse, mutect2, varscan2
- CAMTA1 | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100351815, COSV57888568; called by muse, mutect2, varscan2
- CARMIL2 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100576193; called by muse, mutect2, varscan2
- CASP9 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV100423905; called by muse, mutect2
- CATSPER1 | c.2064+1G>A p.X688_splice | Splice Site (SNP) | VAF 44/266 reads (17%) | catalogued as rs146534093, COSV100376148; called by muse, mutect2, varscan2
- CATSPERG | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99286800; called by muse, mutect2, varscan2
- CBLN2 | c.477+1G>T p.X159_splice | Splice Site (SNP) | VAF 43/115 reads (37%) | catalogued as COSV99504544; called by muse, mutect2, varscan2
- CCDC66 | c.2597G>A p.G866E (on ENST00000394672 / NM_001353147.1; = p.G832E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100414227; called by muse, mutect2, varscan2
- CCN2 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915293, COSV100915347; called by muse, mutect2, varscan2
- CD300C | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100423305, COSV58171492; called by muse, mutect2, varscan2
- CDH7 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100542933, COSV59892652; called by muse, mutect2, varscan2
- CDX4 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV100999147; called by muse, mutect2, varscan2
- CFAP44 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99870172; called by muse, mutect2, varscan2
- CHAT | c.1937C>A p.T646N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100340666; called by muse, mutect2, varscan2
- CHPF | c.774A>T p.Q258H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV99705199; called by muse, mutect2
- CHRNB1 | c.482A>T p.D161V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99548458; called by muse, mutect2, varscan2
- CHST8 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV99381450; called by muse, mutect2, varscan2
- CHSY3 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100519691; called by muse, mutect2, varscan2
- CLCN1 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM960307, COSV100578371; called by muse, mutect2, varscan2
- CMYA5 | c.6886G>T p.G2296C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as COSV101484256; called by muse, mutect2, varscan2
- CNGA3 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99737229; called by muse, mutect2, varscan2
- CNMD | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs755394845, COSV100937309, COSV65033316; called by muse, mutect2, varscan2
- CNTLN | c.2485A>T p.K829* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV99265182; called by muse, mutect2, varscan2
- COL11A1 | c.3496G>T p.G1166C | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs777456846, COSV100617762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL15A1 | c.3181C>A p.P1061T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100897887; called by muse, mutect2, varscan2
- COL15A1 | c.3182C>A p.P1061Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100897888; called by muse, mutect2, varscan2
- COL2A1 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100477162; called by muse, mutect2
- COL7A1 | c.2006G>C p.R669P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.743); catalogued as COSV100096268, COSV100097158; called by muse, mutect2, varscan2
- COQ8A | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV100825770; called by muse, mutect2, varscan2
- CPQ | c.620T>G p.V207G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99613856; called by muse, mutect2, varscan2
- CPXM2 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV99582919; called by muse, mutect2, varscan2
- CRHBP | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV99169516; called by muse, mutect2, varscan2
- CRKL | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as COSV100574180; called by muse, mutect2, varscan2
- CRYGD | c.513A>G p.I171M | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100006109; called by muse, mutect2, varscan2
- CSMD3 | c.8513C>A p.T2838K (on ENST00000297405 / NM_001363185.1; = p.T2669K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99842923; called by muse, mutect2, varscan2
- CTAGE1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101194634, COSV101194635; called by muse, mutect2, varscan2
- CYP4F8 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100358192; called by muse, mutect2, varscan2
- DACT1 | c.1434C>A p.S478R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as rs563561287, COSV100242027, COSV60024214; called by muse, mutect2
- DBF4 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99719522; called by muse, mutect2
- DCC | c.3755C>A p.P1252Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71438146; called by muse, mutect2, varscan2
- DES | c.732A>T p.E244D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as COSV100900532; called by muse, mutect2, varscan2
- DGKE | c.1499G>C p.R500P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs369616072, COSV99401126; called by muse, mutect2, varscan2
- DHX37 | c.1148T>A p.I383N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100439405; called by muse, mutect2, varscan2
- DHX58 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV99288415; called by muse, mutect2, varscan2
- DIDO1 | c.3644G>T p.R1215L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99826658; called by muse, mutect2, varscan2
- DMXL1 | c.2801G>T p.R934I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV100224579; called by muse, mutect2, varscan2
- DNAH11 | c.11446C>T p.H3816Y | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs745855957, COSV100180149; called by muse, mutect2
- DNAH3 | c.12032C>A p.P4011H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769523; called by muse, mutect2, varscan2
- DNAH8 | c.10174C>A p.L3392I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100546662; called by muse, mutect2, varscan2
- DNAJC14 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV100423677; called by muse, mutect2, varscan2
- DPEP2 | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99263196; called by muse, mutect2, varscan2
- DPPA4 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs543557352, COSV100169597; called by muse, mutect2, varscan2
- DSTYK | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100904671; called by muse, mutect2, varscan2
- DYNC2H1 | c.9170A>T p.K3057M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100519347; called by muse, mutect2, varscan2
- DZIP1L | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100551604; called by muse, mutect2, varscan2
- EBF2 | c.1268G>C p.G423A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV101282264; called by muse, mutect2, varscan2
- EPHB6 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235990, COSV67417850; called by muse, mutect2, varscan2
- EPO | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV99402645; called by muse, mutect2, varscan2
- EPO | c.527T>A p.L176H | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99402647; called by muse, mutect2, varscan2
- F2RL2 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV56972163; called by muse, mutect2, varscan2
- FAM50B | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100976591; called by muse, mutect2, varscan2
- FASTKD2 | c.1160A>T p.Q387L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99379149; called by muse, mutect2, varscan2
- FAT1 | c.3077A>T p.N1026I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101499551; called by muse, mutect2, varscan2
- FBN2 | c.2122G>T p.G708* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99329656; called by muse, mutect2, varscan2
- FBXL7 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100310443; called by muse, mutect2
- FBXO42 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV100981668, COSV100981877; called by muse, mutect2, varscan2
- FCGR1A | c.974T>A p.L325* | Nonsense Mutation (SNP) | VAF 168/262 reads (64%) | catalogued as COSV100977303; called by muse, mutect2, varscan2
- FGD1 | c.2327A>T p.N776I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100911223; called by muse, mutect2, varscan2
- FGF10 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52937421, COSV99240869; called by muse, mutect2, varscan2
- FGF6 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99960367; called by muse, mutect2, varscan2
- FNIP2 | c.722G>C p.R241P | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV100033123; called by muse, mutect2, varscan2
- FRY | c.5141G>T p.R1714L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100969721, COSV66571909; called by muse, mutect2, varscan2
- FRYL | c.3594C>A p.N1198K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV99977703; called by muse, mutect2, varscan2
- GABRA4 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.993); catalogued as COSV99974460; called by muse, mutect2, varscan2
- GABRA5 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165585; called by muse, mutect2, varscan2
- GAL3ST2 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99511097; called by muse, mutect2, varscan2
- GALNT13 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101223931; called by muse, mutect2, varscan2
- GALNT15 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.259); catalogued as COSV100327909; called by muse, mutect2, varscan2
- GAS2 | c.875A>T p.K292M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV99535480; called by muse, mutect2, varscan2
- GCSAML | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100826018; called by muse, mutect2, varscan2
- GET4 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99768809; called by muse, mutect2
- GIT1 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.021); catalogued as COSV56404038, COSV99838350; called by muse, mutect2, varscan2
- GPR83 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV54720827, COSV99703833; called by muse, mutect2, varscan2
- GPRIN3 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100310922, COSV60885017, COSV60886005; called by muse, mutect2, varscan2
- GRM7 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1194802660, COSV100737769; called by muse, mutect2, varscan2
- GSDMA | c.1109T>C p.M370T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99227979; called by muse, mutect2
- GUCY2F | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485445; called by muse, mutect2, varscan2
- HCFC1 | c.2777C>G p.P926R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100129628; called by muse, mutect2, varscan2
- HCN3 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100855762; called by muse, mutect2
- HECTD1 | c.4209A>T p.K1403N | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV101237460; called by muse, mutect2, varscan2
- HPS5 | c.869T>C p.L290S (on ENST00000349215 / NM_181507.2; = p.L176S on NM_007216.4) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100834462; called by muse, mutect2, varscan2
- HR | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV100455961, COSV57191191; called by muse, mutect2
- IBSP | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1485346525, COSV99883706; called by muse, mutect2, varscan2
- IL1RAPL2 | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100781758; called by muse, mutect2, varscan2
- IMPG2 | c.3153G>T p.Q1051H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1166984051, COSV99516157; called by muse, mutect2, varscan2
- INMT | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 129/527 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99185108; called by muse, mutect2, varscan2
- INPP5F | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100740305; called by muse, mutect2, varscan2
- INTS6L | c.2539C>G p.H847D | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100878235; called by muse, mutect2, varscan2
- ITGA9 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99293604; called by muse, varscan2
- ITGAL | c.3147C>G p.F1049L | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100776317; called by muse, mutect2, varscan2
- ITPRIP | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99532674; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1276A>G p.I426V (on ENST00000439118 / NM_001008949.3; = p.I434V on NM_178495.6) | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100742228; called by muse, mutect2
- JDP2 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV99966752; called by muse, mutect2, varscan2
- JMJD6 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV100396397; called by muse, mutect2, varscan2
- KCND2 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100477723; called by muse, mutect2, varscan2
- KCNH7 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100037185; called by muse, mutect2, varscan2
- KDM6B | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99642048; called by muse, mutect2, varscan2
- KHNYN | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776666348, COSV99249976; called by muse, mutect2, varscan2
- KLK1 | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032902; called by muse, mutect2, varscan2
- KLRF1 | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99684504; called by muse, mutect2, varscan2
- KRTAP20-1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 11/111 reads (10%) | PolyPhen benign (0.055); catalogued as COSV58168050; called by muse, mutect2, varscan2
- LAMB2 | c.4296T>A p.D1432E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100026402; called by mutect2, varscan2
- LCAT | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.287); catalogued as COSV99863200; called by muse, mutect2
- LCAT | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as rs1030638247, COSV99863202; called by muse, mutect2
- LCE1C | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100908465; called by muse, mutect2, varscan2
- LETMD1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100016484; called by muse, mutect2, varscan2
- LGALSL | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99482519; called by muse, mutect2, varscan2
- LHFPL3 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101308643; called by muse, mutect2, varscan2
- LILRB1 | c.839T>A p.L280Q (on ENST00000427581; = p.L244Q on NM_006669.6) | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100207659; called by muse, mutect2, varscan2
- LILRB4 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99554028; called by muse, mutect2, varscan2
- LILRB5 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs757265271, COSV100300672; called by muse, mutect2, varscan2
- LPP | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771264620, COSV100448013; called by muse, mutect2, varscan2
- LRP1B | c.6215G>A p.G2072E | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756986597, COSV67248800; called by muse, mutect2, varscan2
- LRP6 | c.4735T>C p.S1579P | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1237015416, COSV99744131; called by muse, mutect2, varscan2
- LRRC1 | c.1416G>T p.T472= | Splice Region (SNP) | VAF 14/61 reads (23%) | catalogued as COSV63829737; called by muse, mutect2, varscan2
- LRRIQ1 | c.3374G>T p.W1125L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV67832487; called by muse, mutect2, varscan2
- LRRTM4 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297670, COSV69139188; called by muse, mutect2, varscan2
- LRTM2 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99766228, COSV99766388; called by muse, mutect2, varscan2
- LTN1 | c.4886G>T p.R1629L | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV100798114; called by muse, mutect2, varscan2
- LVRN | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.359); catalogued as rs763801056, COSV63497312; called by muse, mutect2, varscan2
- LYPD4 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100419467; called by muse, mutect2, varscan2
- MACC1 | c.895del p.D299Ifs*7 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV60541539; called by mutect2, pindel, varscan2
- MAML1 | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV99483273; called by muse, mutect2, varscan2
- MAP7D2 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101107485; called by muse, mutect2, varscan2
- MAVS | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100816368; called by muse, mutect2, varscan2
- MCC | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.346); catalogued as COSV100203062; called by muse, mutect2, varscan2
- MED14 | c.4190A>T p.Q1397L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100247581; called by muse, mutect2, varscan2
- MED26 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.734); catalogued as rs141093074; called by muse, mutect2, varscan2
- MEOX2 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV100012399; called by muse, mutect2, varscan2
- MESD | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99930884; called by muse, mutect2, varscan2
- MGLL | c.71A>G p.N24S (on ENST00000398104 / NM_001003794.2; = p.N34S on NM_007283.6) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs771477969, COSV99411565, COSV99412205; called by muse, mutect2, varscan2
- MICAL3 | c.3716C>T p.P1239L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs762023839, COSV101490931; called by muse, mutect2, varscan2
- MIGA1 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100889796; called by muse, mutect2, varscan2
- MRPL35 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99383175; called by muse, mutect2, varscan2
- MRPS18B | c.285+2T>G p.X95_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99457870; called by muse, mutect2, varscan2
- MRPS6 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100758020; called by muse, mutect2, varscan2
- MS4A5 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs368568156; called by muse, mutect2, varscan2
- MTMR8 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100878507; called by muse, mutect2, varscan2
- MUC16 | c.38485G>T p.G12829W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.94); catalogued as COSV101200689; called by muse, mutect2, varscan2
- MUC16 | c.25370G>A p.R8457K | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.119); catalogued as rs1568801266, COSV101200690; called by muse, mutect2, varscan2
- MUC16 | c.24191C>A p.S8064Y | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV101200691, COSV67476204, COSV67492652; called by muse, mutect2, varscan2
- MUC16 | c.8659C>A p.Q2887K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs1465003992, COSV101200692; called by muse, mutect2
- MUC17 | c.12893C>A p.T4298N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100074513, COSV60284880; called by muse, mutect2
- MUC5B | c.13799G>A p.G4600D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.066); catalogued as COSV101500621; called by muse, mutect2, varscan2
- MYH4 | c.5708T>C p.L1903P | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV55127172; called by muse, mutect2, varscan2
- MYH6 | c.2173C>A p.R725S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV100676861; called by muse, mutect2, varscan2
- MYL3 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.08); catalogued as COSV99439551; called by muse, mutect2, varscan2
- MYOM2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.238); catalogued as rs367770117; called by muse, mutect2, varscan2
- NAB2 | c.1276+1G>A p.X426_splice | Splice Site (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100272741; called by muse, mutect2, varscan2
- NAT9 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99380197; called by muse, mutect2, varscan2
- NAV3 | c.683G>T p.R228I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV57101646; called by muse, mutect2, varscan2
- NBEAL1 | c.6496G>T p.E2166* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101355589; called by muse, mutect2, varscan2
- NCOA1 | c.201C>G p.C67W | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946749; called by muse, mutect2, varscan2
- NCOA6 | c.4579A>T p.K1527* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100750240, COSV62862878; called by muse, mutect2, varscan2
- NFATC2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044461; called by muse, mutect2, varscan2
- NIBAN3 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as COSV99962608; called by muse, mutect2, varscan2
- NLRP13 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV100738406; called by muse, mutect2, varscan2
- NLRP3 | c.1873C>A p.Q625K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV60231908; called by muse, mutect2, varscan2
- NOMO2 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100395765; called by muse, mutect2, varscan2
- NOTCH2 | c.4345C>T p.Q1449* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV99865888; called by muse, mutect2, varscan2
- NOX4 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99631459; called by muse, mutect2, varscan2
- NPAS2 | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100176683; called by muse, mutect2, varscan2
- NRAP | c.3842C>A p.A1281D (on ENST00000359988 / NM_001322945.2; = p.A1246D on NM_006175.4) | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780964345, COSV100748545; called by muse, mutect2, varscan2
- NRXN3 | c.1813T>G p.Y605D (on ENST00000335750 / NM_001330195.2; = p.Y232D on NM_004796.6) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100207112; called by muse, mutect2, varscan2
- OGDHL | c.2786A>G p.Q929R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100934451; called by muse, mutect2, varscan2
- OGDHL | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100934452; called by muse, mutect2, varscan2
- OPCML | c.165C>A p.L55= | Splice Region (SNP) | VAF 19/172 reads (11%) | catalogued as COSV100103746, COSV104405697, COSV59454735; called by muse, mutect2, varscan2
- OR10K1 | c.119del p.G40Afs*105 | Frame Shift Del (DEL) | VAF 106/251 reads (42%) | catalogued as COSV56873233; called by mutect2, pindel, varscan2
- OR2D3 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505121; called by muse, mutect2, varscan2
- OR4D11 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100506613; called by muse, mutect2, varscan2
- OR4D9 | c.515A>C p.N172T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100259938; called by muse, mutect2, varscan2
- OR4P4 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100111805; called by muse, mutect2, varscan2
- OSBPL11 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99954435; called by muse, mutect2, varscan2
- OTX2 | c.527C>G p.P176R (on ENST00000408990 / NM_172337.3; = p.P184R on NM_021728.4) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100258043; called by muse, mutect2
- OVCH1 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV99760545; called by muse, mutect2, varscan2
- OXGR1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100037075; called by muse, mutect2, varscan2
- PASK | c.2821G>T p.A941S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV99300008; called by muse, mutect2, varscan2
- PAX1 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.921); catalogued as COSV101270356; called by muse, mutect2, varscan2
- PCDH15 | c.4583G>A p.G1528E (on ENST00000644397 / NM_001354429.2; = p.G1477E on NM_001142769.3) | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100905335; called by muse, mutect2, varscan2
- PCDH15 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100225403; called by muse, mutect2, varscan2
- PCDH15 | c.1338T>A p.N446K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); catalogued as COSV100225407, COSV57279757; called by muse, mutect2, varscan2
- PCDH17 | c.3015G>T p.K1005N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV100931814; called by muse, mutect2, varscan2
- PCDHA4 | c.1320T>A p.S440R | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.093); catalogued as COSV100793639; called by muse, mutect2, varscan2
- PCDHGA2 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV53963775, COSV99542147, COSV99543597; called by muse, mutect2, varscan2
- PCDHGA6 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 24/159 reads (15%) | catalogued as COSV54044182; called by muse, mutect2, varscan2
- PCDHGB6 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99543603; called by muse, mutect2, varscan2
- PCLO | c.5491T>A p.S1831T | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100435833; called by muse, mutect2, varscan2
- PDPR | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as COSV99848673; called by muse, mutect2
- PEAR1 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV99442068; called by muse, mutect2, varscan2
- PEX6 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs753439210, COSV99769916; called by muse, mutect2, varscan2
- PIN1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.15); catalogued as COSV99927693; called by muse, mutect2, varscan2
- PKD1L1 | c.4803A>G p.I1601M | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99220930; called by muse, mutect2, varscan2
- PLCB4 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99596444; called by muse, mutect2
- PLCB4 | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99595091; called by muse, mutect2
- PLG | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99804990; called by muse, mutect2, varscan2
- PLOD3 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV56184091; called by muse, mutect2, varscan2
- PNMA3 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as COSV100937648; called by muse, mutect2, varscan2
- POM121L12 | c.742T>C p.C248R | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV101374921, COSV101374957; called by muse, mutect2, varscan2
- POU6F2 | c.1878T>G p.F626L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV68879078, COSV68884643; called by muse, mutect2, varscan2
- PPFIA2 | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV100334677, COSV61024930; called by muse, mutect2, varscan2
- PPFIA3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100495153; called by muse, mutect2, varscan2
- PRDM1 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100958928; called by muse, mutect2, varscan2
- PREX2 | c.4451G>C p.R1484P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99909050; called by muse, mutect2, varscan2
- PRKCB | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV100334903, COSV104396398; called by muse, mutect2, varscan2
- PRRC2C | c.402A>T p.G134= (on ENST00000367742; = p.G132= on NM_015172.4) | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100145710; called by muse, mutect2, varscan2
- PSG1 | c.729C>G p.Y243* | Nonsense Mutation (SNP) | VAF 89/369 reads (24%) | catalogued as COSV54953980, COSV99741029; called by muse, mutect2, varscan2
- PTPN13 | c.4877A>C p.Q1626P (on ENST00000411767 / NM_080683.3; = p.Q1607P on NM_006264.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100365225, COSV57419038; called by muse, mutect2, varscan2
- PUS10 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.26); catalogued as COSV100369696; called by muse, mutect2, varscan2
- PUS7 | c.309C>G p.D103E | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100708605; called by muse, mutect2, varscan2
- PXDNL | c.2641G>T p.V881F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100685330; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100741402; called by muse, mutect2, varscan2
- RALYL | c.746A>T p.E249V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101569358; called by muse, mutect2, varscan2
- RANBP17 | c.2430G>T p.Q810H | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101206356; called by muse, mutect2, varscan2
- RARS2 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160831989, COSV101057419; called by muse, mutect2, varscan2
- RETSAT | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99806185; called by muse, mutect2, varscan2
- REV3L | c.8426C>T p.T2809I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100725535; called by muse, mutect2
- ROBO2 | c.3451G>T p.A1151S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100168935; called by muse, mutect2, varscan2
- RPE65 | c.1547C>A p.A516D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52019709; called by muse, mutect2, varscan2
- RPL10L | c.278C>G p.P93R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022673, COSV53561638; called by muse, mutect2, varscan2
- RPS6KA5 | c.733A>T p.M245L | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100003000; called by muse, mutect2, varscan2
- RUFY4 | c.1571G>A p.C524Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100723163; called by muse, mutect2, varscan2
- RYR2 | c.5431G>A p.G1811R | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464643419, COSV100772101; called by muse, mutect2, varscan2
- RYR3 | c.3101G>T p.R1034M | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV101213575, COSV66810165; called by muse, mutect2, varscan2
- RYR3 | c.4097C>A p.T1366K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.939); catalogued as COSV101213576; called by muse, mutect2, varscan2
- RYR3 | c.5062T>A p.L1688M | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV101213579; called by muse, mutect2, varscan2
- SAXO2 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV100255856, COSV59753963; called by muse, mutect2, varscan2
- SCN10A | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101479484; called by muse, mutect2, varscan2
- SCN5A | c.2292G>T p.M764I | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100349849, COSV61119137; called by muse, mutect2
- SELENOP | c.445T>A p.L149M | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as COSV100736883; called by muse, mutect2, varscan2
- SELL | c.1069G>T p.A357S (on ENST00000650983; = p.A344S on NM_000655.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV99357736; called by muse, mutect2
- SEMA4G | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99272999; called by muse, mutect2, varscan2
- SEMA5B | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99532774; called by muse, mutect2, varscan2
- SEMA6A | c.1875T>A p.H625Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.255); catalogued as COSV99145884; called by muse, mutect2, varscan2
- SERPINB12 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs755221725, COSV54034203, COSV99501799; called by muse, mutect2, varscan2
- SFXN5 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55585071, COSV99729762; called by muse, mutect2, varscan2
- SH2D4A | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99745029; called by muse, mutect2
- SHANK1 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99521737; called by muse, mutect2
- SIN3A | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 43/190 reads (23%) | catalogued as COSV100845206, COSV64584282; called by muse, mutect2, varscan2
- SLC15A1 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100918222; called by muse, mutect2, varscan2
- SLC18A2 | c.895+1G>T p.X299_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100041909; called by muse, mutect2, varscan2
- SLC5A11 | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61743168; called by muse, mutect2, varscan2
- SLC5A12 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99745318; called by muse, mutect2, varscan2
- SLC5A4 | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV99832077; called by muse, mutect2
- SLC9A2 | c.2110G>T p.V704L | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV52132363, COSV52133991; called by muse, mutect2, varscan2
- SLC9C1 | c.613+2T>A p.X205_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV59886267, COSV99998051; called by muse, mutect2, varscan2
- SLCO4C1 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.433); catalogued as COSV100195543; called by muse, mutect2, varscan2
- SLIT2 | c.2749G>T p.A917S | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.802); catalogued as COSV99886128; called by muse, mutect2, varscan2
- SLITRK2 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100158072; called by muse, varscan2
- SLITRK2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.164); catalogued as COSV100158074, COSV59429078; called by muse, varscan2
- SLITRK2 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100158075; called by muse, mutect2, varscan2
- SNX7 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069327; called by muse, mutect2, varscan2
- SOX9 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV55425131, COSV99818258, COSV99818646; called by muse, mutect2, varscan2
- SPATA31D1 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.759); catalogued as COSV100782382, COSV61202671; called by muse, mutect2, varscan2
- SPATA31E1 | c.426C>G p.S142R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100350829; called by muse, mutect2, varscan2
- SRGAP3 | c.1538A>T p.K513M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100841271; called by mutect2, varscan2
- STAB2 | c.4606A>T p.N1536Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101186186; called by muse, mutect2, varscan2
- STIM1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as COSV100330924; called by muse, mutect2, varscan2
- STK10 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs766523400, COSV99452077; called by muse, mutect2, varscan2
- SUN5 | c.1076T>A p.V359E | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs911851211, COSV100644877; called by muse, mutect2, varscan2
- SVOP | c.1494C>A p.C498* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100139539; called by muse, mutect2
- SYT3 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100144245, COSV58896396; called by muse, mutect2
- SYTL1 | c.1030C>T p.Q344* (on ENST00000543823; = p.Q332* on NM_032872.3) | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as rs1446389377, COSV100539502; called by muse, mutect2
- TAF5 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100674742; called by muse, mutect2, varscan2
- TAS2R30 | c.760A>T p.R254W | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV101115310; called by muse, mutect2, varscan2
- TBC1D8 | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65213926; called by muse, mutect2, varscan2
- TBC1D9 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV101464388, COSV71307689; called by muse, mutect2, varscan2
- TBX4 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99540543; called by muse, mutect2, varscan2
- TCHH | c.2537C>A p.A846D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV100915325; called by muse, mutect2, varscan2
- TENM2 | c.7697C>A p.P2566H (on ENST00000518659 / NM_001122679.2; = p.P2327H on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101319288; called by muse, mutect2
- TLL2 | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100780380; called by muse, mutect2, varscan2
- TLL2 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100780382; called by muse, mutect2, varscan2
- TMEM120A | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100115705; called by muse, mutect2
- TMEM184C | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.026); catalogued as COSV99669751; called by muse, mutect2, varscan2
- TMPRSS15 | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751154905, COSV99518770; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857492; called by muse, mutect2, varscan2
- TOX2 | c.1250C>A p.P417H (on ENST00000358131 / NM_001098798.2; = p.P393H on NM_032883.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV100363221; called by muse, mutect2, varscan2
- TPR | c.5953G>T p.G1985C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100823791, COSV66600411; called by muse, mutect2, varscan2
- TRAM2 | c.345T>G p.N115K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99480335; called by muse, mutect2
- TRIB1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100322572; called by muse, mutect2, varscan2
- TRPM2 | c.4509C>A p.Y1503* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100309144; called by muse, mutect2, varscan2
- UGT2A3 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52359727, COSV99280126; called by muse, mutect2, varscan2
- UNC5A | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99994934; called by muse, mutect2, varscan2
- UNC79 | c.3792C>A p.D1264E (on ENST00000393151 / NM_001346218.2; = p.D1087E on NM_020818.5) | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.667); catalogued as COSV99829262; called by muse, mutect2, varscan2
- UNCX | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | catalogued as COSV100310303, COSV60332803, COSV60332865; called by muse, mutect2, varscan2
- UPK3A | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs867831435, COSV99343197; called by muse, mutect2, varscan2
- USP24 | c.5487T>A p.N1829K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99600578; called by muse, mutect2
- UXS1 | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV99308579; called by muse, mutect2, varscan2
- VAV3 | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV100580140, COSV100580186; called by muse, mutect2, varscan2
- VNN3 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99258529; called by muse, mutect2, varscan2
- WASHC5 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100572981; called by muse, mutect2, varscan2
- WDR20 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779399464, COSV54470531; called by muse, mutect2, varscan2
- WNT10A | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV99297368; called by muse, mutect2, varscan2
- XKR6 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100441000; called by muse, mutect2, varscan2
- ZDBF2 | c.6703C>A p.R2235S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100985257; called by muse, mutect2, varscan2
- ZFHX4 | c.2939G>A p.G980E | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51502646, COSV99266045; called by muse, mutect2, varscan2
- ZNF160 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762432; called by muse, mutect2, varscan2
- ZNF221 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as COSV99240875; called by muse, mutect2, varscan2
- ZNF267 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs777399576, COSV100339884; called by muse, mutect2, varscan2
- ZNF3 | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99447353; called by muse, mutect2, varscan2
- ZNF318 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100546417; called by muse, mutect2, varscan2
- ZNF423 | c.2882G>T p.R961L (on ENST00000563137 / NM_001379286.1; = p.R953L on NM_015069.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.054); catalogued as COSV99283080; called by muse, mutect2, varscan2
- ZNF511 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as rs746249082, COSV100756872; called by muse, mutect2, varscan2
- ZNF536 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as COSV100835597; called by muse, mutect2, varscan2
- ZNF578 | c.1664C>A p.A555E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV101405099; called by muse, mutect2
- ZNF804A | c.2652C>A p.N884K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100169408; called by muse, mutect2, varscan2
- ZNF804B | c.1772G>A p.C591Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60852642; called by muse, mutect2, varscan2
- ZNF831 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 8/173 reads (5%) | catalogued as COSV100926169, COSV64043503; called by muse, mutect2
- ZNF875 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV100183491; called by muse, mutect2, varscan2
- ZSCAN22 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100308450; called by muse, mutect2, varscan2
- ACOT12 | c.1105del p.E369Rfs*9 | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.2083del p.L695Wfs*10 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel, varscan2
- ARMC5 | c.1422del p.D475Tfs*69 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- C14orf39 | c.50-3_50-2del p.X17_splice | Splice Site (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- CLDN14 | c.537_556del p.L180Gfs*95 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- FLRT2 | c.22del p.W8Gfs*9 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel*, varscan2
- IGKV1D-17 | c.330T>A p.C110* | Nonsense Mutation (SNP) | VAF 30/284 reads (11%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- INTS2 | c.2252dup p.N751Kfs*18 | Frame Shift Ins (INS) | VAF 20/125 reads (16%) | called by mutect2, pindel, varscan2
- ITGA6 | c.1430del p.G477Efs*22 (on ENST00000442250; = p.G438Efs*22 on NM_000210.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MARK4 | c.659del p.P220Hfs*74 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | called by mutect2, pindel, varscan2
- METTL25 | c.1683del p.I562Ffs*9 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- MGAT5B | c.154del p.D52Tfs*10 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- NT5DC1 | c.128del p.K43Rfs*12 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- OR4F21 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by mutect2, varscan2
- PGAP4 | c.899_901delinsTT p.Y300Ffs*20 | Frame Shift Del (DEL) | VAF 78/248 reads (31%) | called by pindel, varscan2*
- PLEKHG1 | c.433del p.D145Tfs*43 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- SMYD3 | c.806del p.Q269Rfs*8 (on ENST00000490107 / NM_001375962.1; = p.Q210Rfs*8 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.6961_6965del p.P2321Ifs*58 | Frame Shift Del (DEL) | VAF 8/97 reads (8%) | called by mutect2, pindel
- SULT1B1 | c.260del p.P87Lfs*3 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- TCAF2 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- UHRF1BP1L | c.4369_4371del p.H1457del | In Frame Del (DEL) | VAF 15/89 reads (17%) | called by pindel, varscan2
- VGF | c.400_432del p.P134_E144del | In Frame Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- VPS13D | c.1233del p.F411Lfs*76 | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | called by mutect2, pindel, varscan2
- ABCC2 | c.132C>A p.A44= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV100965638; called by muse, mutect2, varscan2
- ADAMTS12 | c.2994T>C p.S998= | Silent (SNP) | VAF 42/433 reads (10%) | catalogued as rs1216112064, COSV100711488; called by muse, mutect2, varscan2
- AFTPH | c.2727C>T p.D909= (on ENST00000238855 / NM_203437.3; = p.D882= on NM_017657.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99481039; called by muse, mutect2, varscan2
- ANK2 | c.10380A>T p.T3460= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100003269; called by muse, mutect2, varscan2
- ARHGEF17 | c.4065G>T p.L1355= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99736392; called by muse, mutect2, varscan2
- BAZ1B | c.708G>T p.V236= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV100289990; called by muse, mutect2, varscan2
- BCL11B | c.303C>T p.S101= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs267604121, COSV100595762; called by muse, mutect2, varscan2
- BRINP1 | c.1878T>A p.P626= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- BTBD6 | c.1008G>A p.Q336= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100527612; called by muse, mutect2, varscan2
- CCDC127 | c.694A>C p.R232= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV99723095; called by muse, mutect2, varscan2
- CCT8L2 | c.90G>A p.E30= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1441080090, COSV63463040; called by muse, mutect2, varscan2
- CDH6 | c.456C>A p.I152= | Silent (SNP) | VAF 47/394 reads (12%) | catalogued as COSV99420243; called by muse, mutect2, varscan2
- COBLL1 | c.2325T>C p.S775= (on ENST00000392717; = p.S737= on NM_014900.5) | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as COSV99528468; called by muse, mutect2, varscan2
- COQ8B | c.321G>A p.L107= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV99699561; called by muse, mutect2, varscan2
- CR1 | c.36C>T p.V12= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as rs996388913, COSV100888114; called by muse, mutect2
- CRKL | c.672G>T p.G224= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV100574179; called by muse, mutect2, varscan2
- CTNNA2 | c.2751G>T p.V917= (on ENST00000402739 / NM_001282597.3; = p.V869= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/276 reads (21%) | catalogued as COSV100561661, COSV58164468; called by muse, mutect2, varscan2
- CUL2 | c.1434A>G p.T478= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101039245; called by muse, mutect2, varscan2
- DLL4 | c.348G>T p.S116= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99989936; called by muse, mutect2, varscan2
- DNAH9 | c.9276C>T p.A3092= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99307266, COSV99308142; called by muse, mutect2
- DSG3 | c.2661C>T p.P887= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV99934546; called by muse, mutect2, varscan2
- EDNRB | c.765G>A p.E255= (on ENST00000377211 / NM_001201397.1; = p.E165= on NM_000115.5) | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs777080410, COSV57528094; called by muse, mutect2, varscan2
- ERLIN2 | c.642G>A p.A214= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs763446389, COSV99379629; called by muse, mutect2, varscan2
- FAIM | c.88C>A p.R30= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100623977; called by muse, mutect2, varscan2
- FAM50B | c.153G>A p.A51= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100976589; called by muse, mutect2, varscan2
- FAT1 | c.171C>G p.V57= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV101499552; called by muse, mutect2, varscan2
- FBXW10 | c.609A>G p.T203= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs748464601, COSV100111660; called by muse, mutect2, varscan2
- FCRL1 | c.942C>A p.L314= | Silent (SNP) | VAF 81/139 reads (58%) | catalogued as COSV100839855, COSV63826915; called by muse, mutect2, varscan2
- FLG | c.2736T>A p.R912= | Silent (SNP) | VAF 288/971 reads (30%) | catalogued as rs1431415013, COSV100911926; called by muse, mutect2, varscan2
- FLT1 | c.438A>T p.I146= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99164728; called by muse, mutect2, varscan2
- FRAS1 | c.10323T>C p.F3441= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99354707; called by muse, mutect2, varscan2
- FYB2 | c.1029C>T p.S343= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100599704; called by muse, mutect2, varscan2
- FZD10 | c.1497C>G p.P499= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99969256, COSV99969543; called by muse, mutect2, varscan2
- GABRA1 | c.210T>C p.T70= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV99196159; called by muse, mutect2, varscan2
- GDF2 | c.456C>A p.L152= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs781900094; called by muse, mutect2, varscan2
- GLI3 | c.948C>T p.S316= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as rs1458216501, COSV67894745; called by muse, mutect2, varscan2
- GRIA4 | c.336C>A p.A112= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99233562; called by muse, mutect2, varscan2
- H1-6 | c.87G>C p.P29= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100619621; called by muse, mutect2, varscan2
- HHATL | c.756C>A p.G252= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100124570; called by muse, mutect2, varscan2
- HOXA2 | c.366C>A p.T122= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs764835609, COSV99761229; called by muse, varscan2
- IFIH1 | c.282C>T p.Y94= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as rs1197144008, COSV99718790; called by muse, mutect2, varscan2
- ITPR2 | c.7977G>C p.L2659= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV101190102; called by muse, mutect2, varscan2
- KDM8 | c.279G>C p.R93= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99619840; called by muse, mutect2, varscan2
- KIF24 | c.888A>T p.P296= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100799268; called by mutect2, varscan2
- KLHL1 | c.801C>A p.V267= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV100917867, COSV64768603, COSV64777932; called by muse, mutect2, varscan2
- KRT75 | c.1062C>A p.G354= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV99359540; called by muse, mutect2, varscan2
- KYAT3 | c.240T>C p.Y80= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV99556750; called by muse, mutect2, varscan2
- LAS1L | c.1719G>A p.E573= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100408646; called by muse, mutect2, varscan2
- LCT | c.2544C>A p.L848= | Silent (SNP) | VAF 83/337 reads (25%) | catalogued as COSV99930126; called by muse, mutect2, varscan2
- LHFPL3 | c.444C>A p.G148= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV101308645; called by muse, mutect2, varscan2
- LILRA4 | c.822G>C p.G274= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99393302; called by muse, mutect2, varscan2
- LTBP1 | c.1302C>A p.V434= (on ENST00000404816 / NM_206943.4; = p.V108= on NM_000627.4) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100616719, COSV100617785; called by muse, mutect2, varscan2
- MAGEB1 | c.288C>A p.A96= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100975065; called by muse, mutect2, varscan2
- MEIS2 | c.207C>G p.V69= (on ENST00000561208 / NM_170675.5; = p.V56= on NM_002399.3) | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV54940322, COSV99576977; called by muse, mutect2, varscan2
- MOGAT3 | c.501T>C p.C167= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs768590342, COSV99777263; called by muse, mutect2, varscan2
- MRPS6 | c.237G>C p.V79= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100758019; called by muse, mutect2, varscan2
- MUC16 | c.2880T>A p.A960= | Silent (SNP) | VAF 44/249 reads (18%) | catalogued as COSV101200693; called by muse, mutect2, varscan2
- MYH1 | c.1890G>A p.A630= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs377184878; called by muse, mutect2, varscan2
- NAT10 | c.1188C>G p.P396= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as rs771255449, COSV99140337; called by muse, mutect2, varscan2
- NIBAN3 | c.501T>C p.A167= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV99962606; called by muse, mutect2, varscan2
- NLRP3 | c.159C>A p.A53= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs200788923, COSV100276453; called by muse, mutect2, varscan2
- NOTCH2 | c.7415G>A p.*2472= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV99865885; called by muse, mutect2, varscan2
- NPHS1 | c.1404C>T p.I468= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as rs369636803; called by muse, mutect2, varscan2
- NT5DC2 | c.261C>T p.P87= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs368529682; called by muse, mutect2, varscan2
- NUP210 | c.1194G>A p.E398= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99596751; called by muse, mutect2, varscan2
- OCA2 | c.1470C>T p.V490= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100668371; called by muse, mutect2, varscan2
- OR14K1 | c.333C>A p.G111= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1222574663, COSV51720544; called by muse, mutect2, varscan2
- OR2M2 | c.228C>T p.T76= | Silent (SNP) | VAF 119/471 reads (25%) | catalogued as rs754757872, COSV100677290; called by muse, mutect2, varscan2
- OR5W2 | c.594G>A p.V198= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs769893790, COSV60614788; called by muse, mutect2, varscan2
- OR7G1 | c.481C>T p.L161= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs1182300720, COSV99528715; called by muse, mutect2, varscan2
- OTUD7B | c.1668G>C p.L556= | Silent (SNP) | VAF 29/420 reads (7%) | catalogued as COSV100967683; called by muse, mutect2
- OTULIN | c.315T>C p.C105= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99419940; called by muse, mutect2
- PCDH17 | c.1473G>C p.L491= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100931813; called by muse, mutect2
- PCDHGA3 | c.1797C>A p.G599= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99543599; called by muse, mutect2, varscan2
- PHF8 | c.2697G>T p.G899= (on ENST00000357988 / NM_001184896.1; = p.G863= on NM_015107.3) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100154635; called by muse, mutect2, varscan2
- PLEC | c.11247G>T p.R3749= (on ENST00000322810 / NM_201380.4; = p.R3639= on NM_000445.5) | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV100517306, COSV59633883; called by muse, mutect2, varscan2
- POM121L12 | c.165G>T p.L55= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs374979505, COSV101374860, COSV68693732; called by muse, varscan2
- PRAG1 | c.1755C>A p.P585= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100422589; called by muse, mutect2
- PRODH2 | c.990C>A p.A330= (on ENST00000301175; = p.A254= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99995451; called by muse, mutect2, varscan2
- PRSS48 | c.747T>G p.P249= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV101490182; called by muse, mutect2, varscan2
- PTPRC | c.1794C>G p.L598= | Silent (SNP) | VAF 21/193 reads (11%) | catalogued as COSV100722932; called by muse, mutect2, varscan2
- RERGL | c.348A>T p.S116= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV99968020; called by muse, mutect2, varscan2
- RESF1 | c.4362G>A p.K1454= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV100440511; called by muse, mutect2, varscan2
- RIOX2 | c.660G>T p.P220= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.12588C>A p.T4196= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100772102; called by muse, mutect2
- SALL1 | c.1785C>A p.S595= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV51757369, COSV99179225; called by muse, mutect2, varscan2
- SCUBE1 | c.1245C>T p.P415= | Silent (SNP) | VAF 37/201 reads (18%) | catalogued as rs932825819, COSV100683554; called by muse, mutect2, varscan2
- SI | c.4998C>G p.G1666= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100016638, COSV52295544; called by muse, mutect2, varscan2
- SLC14A1 | c.522C>A p.P174= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV58933443, COSV58934013; called by muse, mutect2, varscan2
- SLC18A2 | c.816G>T p.P272= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs200513145, COSV100041906; called by muse, mutect2
- SLC8A2 | c.1755C>T p.D585= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99370221; called by muse, mutect2
- SORCS3 | c.1374G>A p.T458= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs150451910; called by muse, mutect2, varscan2
- SRD5A3 | c.633C>T p.I211= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV99948134; called by muse, mutect2, varscan2
- SUPT5H | c.2751C>T p.S917= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV63238833; called by muse, mutect2, varscan2
- TECTA | c.3717T>A p.G1239= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99881001; called by muse, mutect2, varscan2
- TLL2 | c.1506G>T p.V502= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100780176; called by muse, mutect2, varscan2
- TLR10 | c.1935T>A p.S645= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100457906; called by muse, mutect2, varscan2
- TM9SF3 | c.312A>T p.P104= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100951874; called by muse, mutect2, varscan2
- TMEM117 | c.1011G>C p.G337= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99863326; called by muse, mutect2, varscan2
- TRPV6 | c.1914G>T p.V638= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs756611380, COSV100844385; called by muse, mutect2, varscan2
- TSHZ3 | c.2238C>A p.P746= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV99552251, COSV99552317; called by muse, mutect2, varscan2
- TTYH1 | c.144G>C p.A48= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as COSV100002305; called by muse, mutect2, varscan2
- UGT2B11 | c.1008G>T p.L336= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV101485277; called by muse, mutect2, varscan2
- USP4 | c.2247T>C p.L749= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99649590; called by muse, mutect2, varscan2
- USP4 | c.669A>C p.T223= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99649594; called by muse, mutect2, varscan2
- VWF | c.3150C>A p.I1050= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99779761; called by muse, mutect2, varscan2
- XIRP2 | c.9216T>C p.A3072= (on ENST00000628543; = p.A3247= on NM_152381.6) | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99745948; called by muse, mutect2, varscan2
- XKR4 | c.48C>T p.D16= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1219724103, COSV100532029; called by muse, mutect2, varscan2
- ZBED9 | c.273C>T p.I91= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV101509353; called by muse, mutect2, varscan2
- ZNF423 | c.2883G>T p.R961= (on ENST00000563137 / NM_001379286.1; = p.R953= on NM_015069.4) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99283077; called by muse, mutect2, varscan2
- ZNF692 | c.37C>A p.R13= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1301988936, COSV100133902; called by muse, mutect2
- AMFR | c.*683G>A | 3'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99316131; called by muse, mutect2, varscan2
- ASIC2 | c.556-179381A>G | Intron (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99860765; called by muse, mutect2, varscan2
- CPLANE1 | c.*5522G>A | 3'UTR (SNP) | VAF 149/405 reads (37%) | catalogued as rs747294401, COSV99951305; called by muse, mutect2, varscan2
- CTBP2 | c.58+11583G>C | Intron (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100456771; called by muse, mutect2, varscan2
- DCHS2 | n.8415C>A | RNA (SNP) | VAF 88/203 reads (43%) | catalogued as COSV100602319; called by muse, mutect2, varscan2
- DST | c.4297-2409G>A | Intron (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99758714; called by muse, mutect2, varscan2
- FBLN2 | c.2155+1954G>T | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99852418; called by muse, mutect2, varscan2
- KIR3DX1 | n.864C>T | RNA (SNP) | VAF 15/129 reads (12%) | catalogued as rs760842823, COSV55597926; called by muse, mutect2, varscan2
- MARCHF1 | c.163-40C>A | Intron (SNP) | VAF 24/83 reads (29%) | catalogued as COSV99922203, COSV99922419; called by muse, mutect2, varscan2
- RGS8 | chr1:182672820 C>G | 5'Flank (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99276836; called by muse, mutect2, varscan2
- SSPOP | n.7350G>C | RNA (SNP) | VAF 7/26 reads (27%) | catalogued as rs959207917, COSV100022804; called by muse, mutect2
